Somatic mutation profile of tumor specimen BA2528D (aliquot aq-BA2528D) from BEATAML1.0 case 2531, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 75.8 years (27,677 days).
Specimen BA2528D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c75a39f1-d2ee-41a6-acfa-f234dd63dd0c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2493D (Solid Tissue Normal), aliquot aq-BA2493D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/07e1b5e1-e476-4212-ac8f-c75b7a3f67ae

The open-access MAF lists 24 somatic variants for this specimen: 19 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 4, Nonsense Mutation 2, Frame Shift Ins 2, Frame Shift Del 1, 3'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNMT3A | c.2645G>A p.R882H | Missense Mutation (SNP) | VAF 36/78 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.067); catalogued as rs147001633, COSV53036153, COSV53040144, COSV53040431; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, varscan2
- PHF6 | c.820C>T p.R274* (on ENST00000332070 / NM_032458.3; = p.R275* on NM_032335.3) | Nonsense Mutation (SNP) | VAF 42/109 reads (39%) | catalogued as rs1556019107, COSV59699330; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SF3B1 | c.2098A>G p.K700E | Missense Mutation (SNP) | VAF 29/80 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs559063155, COSV59205318, COSV59216586; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- C5orf52 | c.304C>T p.R102* | Nonsense Mutation (SNP) | VAF 36/120 reads (30%) | catalogued as rs964493376; called by muse, mutect2, varscan2
- CCDC42 | c.808G>A p.V270M | Missense Mutation (SNP) | VAF 59/185 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1424864420; called by muse, mutect2, varscan2
- CMYA5 | c.2463A>C p.Q821H | Missense Mutation (SNP) | VAF 44/118 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.846); catalogued as COSV71410187; called by muse, mutect2, varscan2
- TMEM232 | c.11C>T p.P4L | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.221); catalogued as COSV70267125; called by muse, mutect2
- ACAD8 | c.553C>A p.L185I | Missense Mutation (SNP) | VAF 111/391 reads (28%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.599); called by muse, varscan2
- AHNAK2 | c.5945C>T p.T1982I | Missense Mutation (SNP) | VAF 98/418 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.486); called by muse, varscan2
- LRRC14B | c.106C>T p.L36F | Missense Mutation (SNP) | VAF 40/104 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- NOL8 | c.3205G>A p.G1069R | Missense Mutation (SNP) | VAF 94/255 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- NOTCH1 | c.6598G>T p.V2200L | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- OR10Q1 | c.366G>T p.M122I | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.012); called by muse, mutect2
- POC1B | c.101-1G>T p.X34_splice | Splice Site (SNP) | VAF 4/40 reads (10%) | called by muse, mutect2
- RUNX1 | c.955dup p.R319Pfs*254 (on ENST00000344691 / NM_001001890.3; = p.R346Pfs*254 on NM_001754.5) | Frame Shift Ins (INS) | VAF 6/16 reads (38%) | called by mutect2, varscan2
- SDHA | c.17del p.G6Afs*6 | Frame Shift Del (DEL) | VAF 14/32 reads (44%) | called by mutect2, pindel, varscan2
- SEMA4B | c.128C>A p.A43E | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.604); called by muse, mutect2
- STAG2 | c.2336dup p.N780Efs*5 | Frame Shift Ins (INS) | VAF 39/82 reads (48%) | called by mutect2, pindel, varscan2
- TET1 | c.4396A>G p.I1466V | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.869); called by mutect2, varscan2
- CALCOCO2 | c.525T>C p.A175= | Silent (SNP) | VAF 37/92 reads (40%) | called by muse, mutect2, varscan2
- MXRA5 | c.1560C>T p.I520= | Silent (SNP) | VAF 22/24 reads (92%) | called by muse, mutect2, varscan2
- PCTP | c.495C>A p.G165= | Silent (SNP) | VAF 4/31 reads (13%) | called by muse, mutect2
- TRPM3 | c.2922G>A p.R974= (on ENST00000357533 / NM_001366142.2; = p.R817= on NM_020952.6) | Silent (SNP) | VAF 66/225 reads (29%) | catalogued as rs764212549; called by muse, mutect2, varscan2
- WDR46 | c.*1G>T | 3'UTR (SNP) | VAF 5/61 reads (8%) | called by muse, mutect2
